Somatic mutation profile of tumor specimen TCGA-DX-AB2H-01A (aliquot TCGA-DX-AB2H-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB2H, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 81.0 years (29,569 days).
Specimen TCGA-DX-AB2H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 797e800d-704a-46af-89da-5b5ea449e9ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2H-10A (Blood Derived Normal), aliquot TCGA-DX-AB2H-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/604bf112-b9fb-493c-80e6-bf3b0b1a6bc0

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 29, Silent 10, Frame Shift Del 6, Splice Region 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559873550, CM148114, COSV101170040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALB | c.1287T>C p.N429= | Splice Region (SNP) | VAF 14/64 reads (22%) | catalogued as rs780586176, COSV99890927; called by muse, mutect2, varscan2
- ARID2 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 20/503 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV100535578; called by muse, mutect2
- ASXL2 | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs770140134, COSV99710431; called by muse, mutect2, varscan2
- C6 | c.513G>C p.R171S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99666651; called by muse, mutect2, varscan2
- CCDC68 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765362415, COSV61603168; called by muse, mutect2, varscan2
- CNGA3 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs149802213, CM154640, COSV55626605; called by muse, mutect2, varscan2
- COL5A3 | c.2945A>G p.K982R | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774292865, COSV53418303; called by muse, mutect2, varscan2
- DDB2 | c.67A>G p.R23G | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99921490; called by muse, mutect2, varscan2
- ENPP5 | c.497G>C p.R166T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100040332; called by muse, mutect2, varscan2
- ESYT1 | c.84del p.A29Lfs*27 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs1462675034; called by pindel, varscan2
- FEZF2 | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs751198698, COSV99334545; called by muse, mutect2, varscan2
- GAB4 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs762931159, COSV101271901; called by muse, mutect2, varscan2
- GLCCI1 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99780161; called by muse, mutect2, varscan2
- GLCCI1 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV99780165; called by muse, mutect2, varscan2
- GOLPH3L | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99653646; called by muse, mutect2
- GPR101 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981284; called by muse, mutect2, varscan2
- KDM5B | c.2879G>T p.R960L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV52507201, COSV99350192; called by muse, mutect2
- KIF21A | c.2482G>A p.E828K (on ENST00000361418 / NM_001378440.1; = p.E815K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 334/710 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV100735341; called by muse, varscan2
- LRRC8B | c.2096A>C p.Q699P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV100446462; called by muse, mutect2, varscan2
- PCDH7 | c.2594T>C p.I865T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100687696; called by muse, mutect2, varscan2
- PCDHA6 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV100972152; called by muse, mutect2, varscan2
- PDE3B | c.3299A>C p.D1100A | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99962119; called by muse, mutect2, varscan2
- RNF220 | c.1617G>T p.W539C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100131870; called by muse, mutect2
- SCNN1G | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263978; called by muse, mutect2, varscan2
- SLC4A4 | c.1500C>T p.G500= (on ENST00000264485 / NM_001098484.3; = p.G456= on NM_003759.4) | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as rs373128647, COSV52625740; called by muse, mutect2, varscan2
- STYK1 | c.1206A>C p.E402D | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV99311648; called by muse, mutect2, varscan2
- TSPAN19 | c.604A>T p.N202Y | Missense Mutation (SNP) | VAF 387/1667 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV101468073; called by muse, mutect2, varscan2
- USP20 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs368117192; called by muse, mutect2, varscan2
- VPS13A | c.2783C>A p.A928D | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100652303; called by muse, mutect2, varscan2
- ZBTB7A | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59328764; called by muse, mutect2, varscan2
- ZNF592 | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55436545; called by muse, mutect2, varscan2
- BRD7 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- DCLRE1A | c.2068_2083del p.S690Dfs*60 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- EXOSC8 | c.389del p.K130Sfs*28 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | called by mutect2, pindel, varscan2
- HR | c.2666_2669del p.E889Vfs*12 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- ITPR1 | c.7385del p.F2462Sfs*10 (on ENST00000354582; = p.F2407Sfs*10 on NM_002222.7) | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- R3HDM1 | c.2308_2321del p.P770Cfs*85 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1641C>T p.Y547= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99497309; called by muse, mutect2
- CALCR | c.1356C>T p.G452= (on ENST00000649521 / NM_001164737.2; = p.G436= on NM_001742.4) | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs751428108, COSV100810434; called by muse, mutect2
- DDI1 | c.870T>C p.A290= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100158152; called by muse, mutect2, varscan2
- DUSP13 | c.531G>A p.R177= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs373934068; called by muse, mutect2, varscan2
- DYNC2H1 | c.3552A>G p.Q1184= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV100517791; called by muse, mutect2, varscan2
- MAGEC3 | c.1008G>A p.R336= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV100024981; called by muse, mutect2, varscan2
- SLC35A5 | c.1158G>A p.R386= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99656721, COSV99656763; called by muse, mutect2, varscan2
- TMEM217 | c.555G>T p.S185= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV100362482, COSV100362689; called by muse, mutect2, varscan2
- TTN | c.78129G>A p.V26043= (on ENST00000591111; = p.V18619= on NM_003319.4) | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as COSV100598568; called by muse, mutect2, varscan2
- XKR8 | c.858C>A p.I286= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100871881; called by muse, mutect2, varscan2
